Gene-level copy-number profile of tumor specimen TCGA-DX-A1KY-01A from TCGA case TCGA-DX-A1KY, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.5 years (24,281 days).
Specimen TCGA-DX-A1KY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a0fb417a-a4c6-45c0-bcfa-b31b3e7acf31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1KY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44cca828-e631-4b4f-a92b-a580d52b8dd2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 8,820; copy number 2: 29,784; copy number 3: 14,371; copy number 4: 2,834; copy number 5: 1,968; copy number 6: 889; copy number 7: 292; copy number 8: 327; copy number 9: 180; copy number 10: 8; copy number 11: 71; copy number 12: 4; copy number 13: 200; copy number 15: 10; copy number 18: 1; copy number 21: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1KY-01A-11D-A24M-01): tumor purity 0.95, ploidy 2.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–19,407,962, 41 genes (within-gene range 0–1): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3.
- chr13:20,403,666–20,567,045, 3 genes: CRYL1, MIR4499, AL590096.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,607 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–169,103,276, 997 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:169,367,970–174,160,165, 111 genes, copy number 6–11 (broad region; genes not listed).
- chr1:174,367,105–174,368,039, 1 gene, copy number 6: AL022400.1.
- chr1:176,616,273–176,616,786, 1 gene, copy number 5: PTP4A1P7.
- chr1:181,668,749–181,669,028, 1 gene, copy number 5: Metazoa_SRP.
- chr1:182,712,862–184,171,823, 31 genes, copy number 6 (within-gene range 2–6): LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA.
- chr3:11,745–846,561, 11 genes, copy number 6–12 (within-gene range 3–12): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32.
- chr3:6,148,484–6,365,885, 2 genes, copy number 6: AC026167.1, AC027119.1.
- chr3:7,519,741–8,611,924, 6 genes, copy number 6 (within-gene range 3–6): GRM7-AS1, AC077690.1, LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P.
- chr3:10,566,255–11,557,665, 15 genes, copy number 5 (within-gene range 3–5): ATP2B2-IT1, ATP2B2-IT2, LINC00606, AC018495.1, SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1.
- chr3:17,990,023–18,041,603, 2 genes, copy number 6: AC132807.1, AC132807.2.
- chr3:18,954,943–19,985,175, 7 genes, copy number 6 (within-gene range 2–6): RNU6-138P, KCNH8, MIR4791, AC061958.1, EFHB, HSPA8P18, RAB5A.
- chr3:23,389,661–25,174,305, 21 genes, copy number 5: AC121251.1, RNU6-922P, RNU6-788P, UBE2E1-AS1, UBE2E1, ARL4AP4, NKIRAS1, RPL15, NR1D2, LINC00691, NPM1P23, THRB, RPL31P20, THRB-IT1, THRB-AS1, AC012087.2, AC012087.1, EIF3KP2, AC092422.1, RN7SL216P, RNA5SP125.
- chr3:28,241,584–30,305,037, 16 genes, copy number 6: CMC1, AZI2, ZCWPW2, AC098650.1, FAM96AP1, AC093142.1, RBMS3, RBMS3-AS3, MESTP4, RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3.
- chr4:573,880–2,756,342, 74 genes, copy number 5–6 (broad region; genes not listed).
- chr4:5,051,480–6,884,170, 31 genes, copy number 5 (within-gene range 4–5): STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC, CRMP1, C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232.
- chr4:7,754,077–12,312,690, 121 genes, copy number 5–8 (broad region; genes not listed).
- chr4:13,568,738–23,768,652, 98 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:24,517,441–25,619,468, 21 genes, copy number 6 (within-gene range 4–6): DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P.
- chr7:78,939,850–79,675,015, 12 genes, copy number 5: MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1.
- chr7:82,754,012–84,492,724, 8 genes, copy number 5 (within-gene range 4–5): PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A.
- chr7:110,662,644–112,206,407, 10 genes, copy number 15 (within-gene range 3–15): IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1.
- chr7:151,148,589–151,954,985, 26 genes, copy number 5: GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1.
- chr7:153,144,313–153,449,875, 4 genes, copy number 5: AC079809.1, LINC01287, AC073236.1, PAXBP1P1.
- chr7:153,968,665–154,063,325, 3 genes, copy number 7: AC005588.1, AC006019.3, AC006019.1.
- chr7:154,928,460–156,893,216, 41 genes, copy number 5–7 (within-gene range 3–7): PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P.
- chr8:46,028,804–142,209,003, 1,369 genes, copy number 5–6 (broad region; genes not listed).
- chr12:38,906,451–42,717,120, 56 genes, copy number 6: CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450.
- chr12:68,272,443–68,971,570, 26 genes, copy number 7 (within-gene range 2–7): MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,359,710–69,699,476, 11 genes, copy number 7: YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:70,638,073–70,920,738, 1 gene, copy number 6 (within-gene range 2–6): PTPRR.
- chr12:70,906,917–74,402,600, 37 genes, copy number 6 (within-gene range 1–6): Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394.
- chr12:79,773,563–81,759,553, 28 genes, copy number 8 (within-gene range 2–8): PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr13:41,101,019–41,236,686, 6 genes, copy number 5 (within-gene range 1–5): MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7.
- chr13:55,535,697–58,752,233, 23 genes, copy number 5: AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1.
- chr17:15,789,016–16,804,453, 43 genes, copy number 5 (within-gene range 3–5): AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A, AC127540.2, ZNF287, AC127540.1, SRSF6P2, ZNF624, AC098850.2, NEK4P2, RNASEH1P2, CCDC144A, AC098850.3, RNU6-405P, RN7SL620P, UPF3AP1.
- chr17:17,383,377–18,506,313, 61 genes, copy number 5 (broad region; genes not listed).
- chr18:35,241,030–35,979,286, 25 genes, copy number 5 (within-gene range 2–5): ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21.
- chr19:6,661,253–7,472,484, 28 genes, copy number 13 (within-gene range 3–13): TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18.
- chr19:9,261,015–12,696,631, 217 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
